PECGS case C083-000027 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/592cd42c-b738-413e-98e0-44cf14803069

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 31 years; Year of birth: 1988; Education level: Vocational College or Some College.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 30.7 years (11,213 days); AJCC clinical stage: Stage IIIB; Progression or recurrence: no.

Other clinical attributes
- BMI: 26.63.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 0.75; Alcohol history: Yes.

Biospecimens (2 samples)
- Sample C083-000027_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000027_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
